Somatic mutation profile of tumor specimen MP2PRT-PARMRR-TMP1-A (aliquot MP2PRT-PARMRR-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARMRR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,088 days).
Specimen MP2PRT-PARMRR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8884b457-5342-4b05-b06c-02500c8c01bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMRR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMRR-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7182aac1-ecc3-49a6-81d4-4681c2b13e21

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Intron 1, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 83/406 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOBEC3C | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 23/398 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs201038131, COSV99328962; called by muse, mutect2
- APOBEC4 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV58018467; called by muse, mutect2
- C6orf118 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 16/446 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV100025014; called by muse, mutect2
- CTSC | c.164C>G p.S55W | Missense Mutation (SNP) | VAF 142/363 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377512795; called by muse, mutect2, varscan2
- EMSY | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 25/325 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767815359; called by muse, mutect2
- MPHOSPH9 | c.3370G>C p.E1124Q | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56616746, COSV56619256; called by muse, mutect2, varscan2
- PCLO | c.11244G>C p.R3748S | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV100426659, COSV61659566; called by muse, mutect2
- SPATA31D4 | c.2499G>C p.K833N | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV100542021, COSV100542033, COSV100542039; called by muse, mutect2, varscan2
- TLN2 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 15/295 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100169268, COSV60891066; called by muse, mutect2
- VN1R4 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 123/340 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.06); catalogued as rs1193097584, COSV60805008; called by muse, mutect2, varscan2
- WHRN | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 90/401 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755922335; called by muse, mutect2, varscan2
- C6orf141 | c.75C>G p.S25R | Missense Mutation (SNP) | VAF 134/562 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2
- CATSPER2 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 240/735 reads (33%) | called by mutect2, pindel, varscan2
- EPB41L3 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 208/604 reads (34%) | called by muse, mutect2, varscan2
- GPR12 | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 17/420 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.139); called by muse, mutect2
- KCND3 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 20/468 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- MZF1 | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 26/943 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2
- NAPSA | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 11/354 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- NUP98 | c.3467G>A p.S1156N (on ENST00000359171 / NM_001365126.1; = p.S1139N on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/410 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PHACTR2 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 18/441 reads (4%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- PHF3 | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- PPP1R2B | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 15/389 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SLC17A2 | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.297); called by muse, mutect2
- SLC43A2 | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2
- ZNF157 | c.1433C>A p.A478D | Missense Mutation (SNP) | VAF 122/143 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZNF606 | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- CRTAC1 | c.1422G>C p.L474= | Silent (SNP) | VAF 22/579 reads (4%) | catalogued as COSV100085375; called by muse, mutect2
- CSMD3 | c.1572C>T p.I524= (on ENST00000297405 / NM_001363185.1; = p.I420= on NM_052900.3) | Silent (SNP) | VAF 76/355 reads (21%) | called by muse, mutect2, varscan2
- KIAA0930 | c.924G>A p.K308= (on ENST00000336156 / NM_001009880.2; = p.K313= on NM_015264.2) | Silent (SNP) | VAF 118/521 reads (23%) | called by muse, mutect2, varscan2
- OR11A1 | c.300C>G p.L100= | Silent (SNP) | VAF 26/779 reads (3%) | called by muse, mutect2
- POU3F4 | c.159C>T p.L53= | Silent (SNP) | VAF 12/312 reads (4%) | catalogued as rs1377955293, COSV64537841; called by muse, mutect2
- PRKDC | c.9690G>A p.L3230= | Silent (SNP) | VAF 111/375 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.26841C>T p.F8947= (on ENST00000591111; = p.F8020= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/234 reads (29%) | called by muse, mutect2, varscan2
- ZNF621 | c.891C>G p.G297= | Silent (SNP) | VAF 74/334 reads (22%) | called by muse, mutect2, varscan2
- DUSP13 | c.*638C>T | 3'UTR (SNP) | VAF 121/350 reads (35%) | catalogued as rs200011059; called by muse, mutect2, varscan2
- NPHP1 | c.1926+330C>G | Intron (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
